Surgical pathology report (de-identified scan), TCGA case TCGA-36-1577, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1577-01A (Primary Tumor).

[page 1 of 3]
TCGA-36-1577

Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering Physician:

Final Diagnosis:

A. Left salpingo-oophorectomy showing:

1. Endometrioid adenocarcinoma of the ovary: No definite surface Component.
2. FIGO tumor histologic grade II.
3. Defect in wall of solid and cystic tumour-surgical correlation necessary, but presumably area where adherent to the pelvic side wall-see below
4. Unremarkable fallopian tube.

B. Right salpingo-oophorectomy showing:

1. Endometrioid adenocarcinoma of the ovary.
2. FIGO histologic tumor grade II/III.
3. The ovarian surface is involved by malignancy.
4. Unremarkable fallopian tube.

C. Specimen labelled "adhesions sigmoid colon" showing fibrovascular tissue with endometriosis, negative for malignant cells.

D. Specimen labelled "adhesions left pelvis sidewall" showing fibrovascular tissue with one surface of one section positive for a microscopic deposit of endometrioid adenocarcinoma.

E. Total hysterectomy showing:

1. Endometriosis of cul-de-sac, negative for malignant cells.
2. Disordered proliferative endometrium.
3. Serosal surface is unremarkable, negative for adhesions or malignant cells.
4. Unremarkable cervix without dysplasia.

F. Specimen labelled "hepatic flexure biopsy" showing fibrovascular fatty tissue with papillary mesothelial hyperplasia, negative for malignant cells.

G. Specimen labelled "omentum" showing extensive papillary mesothelial hyperplasia, negative for malignancy.

H. Specimen labelled "adhesions cul-de-sac" showing hemorrhagic vascular tissue with reactive stromal cells and hemosiderin pigmentation, features consistent with endometriosis, negative for malignant cells.

Final Diagnosis Comment:

The endometrioid carcinoma of surface epithelial derivation may well have arisen in endometriosis which has been obliterated, in that there is cul de sac endometriosis identified. The malignancy has some areas which are cytologically low grade and others that are high

[page 2 of 3]
grade cytologically. The malignancy is predominantly gland forming eg Grade I but the higher focal cytologic grade would allow this to be designated as an histologic Grade II malignancy. Note that there is definite squamous "metaplastic" differentiation in the malignancy as is typical of endometrioid carcinomas.

Clinical History as Provided by Submitting Physician:

4 [REDACTED] ss. Elevated CA125

Ascites, Right pleural effusion

?Primary epithelial vs. met ??stomach

A. Left ovary (for frozen section)

B. Right ovary

C. Adhesions sigmoid colon

D. Adhesions left pelvis sidewall

E. Uterus and cervix

F. Hepatic flexure biopsy

G. Omentum

H. Adhesion cul-de-sac

Specimens Received:

A: left ovary + tube

B: right ovary

C: adhesions sigmoid colon

D: adhesions left pelvis side wall

E: uterus & cervix

F: hepatic flexure biopsy

G: omentum

H: adhesion cul de sac

Gross Description:

Specimen is received in eight containers each labelled with the patient's name.

Container "A" is labelled "left ovary" and consists of a salpingo-oophorectomy specimen weighing 330 g and the mass measuring 10 x 9 x 5 cm with attached fallopian tube measuring 5 cm long x 0.3 cm in diameter. There is a defect in the outer surface of the mass and this defect measures 6 x 3.5 cm. It is not clear whether this defect is artifactual or real rupture of the outer surface of the tumour. The defect area is painted with black ink. Otherwise the outer surface of the tumour is smooth and unremarkable. The cut surface of the tumour is solid, fleshy in appearance. The fallopian tube grossly looks unremarkable.

Representative sections are submitted as follows:

"A1-A2" -frozen section resubmitted in toto.

"A3-A5" -tumour

"A6-A8" -tumour in relation to the defect

"A9" -fallopian tube.

Container "B" is labelled "right ovary and fallopian tube" and consists of A right salpingo-oophorectomy specimen weighing 1,011 g and measuring 18 x 11 x 7 cm with an attached fallopian tube measuring 4 x 0.3 cm. The mass received as ruptured cyst has three grey-white outer surface nodules, the largest measuring 4 cm in greatest dimension, and the smallest measuring 2cm in greatest dimension and these outer surface nodules are painted with black ink. The cut surface of the tumour is solid, partially cystic. The solid part is grey-white and represents about 70% of the tumour. The inner lining of the cystic part is nodular grey-white. The fallopian tube is grossly unremarkable.

Representative sections are submitted as follows:

"B1-B3" -solid part of the tumour

"B4-B5" -cystic part of the tumour

"B6-B9" -tumour in relation to the surface nodules

"B10" -fallopian tube.

Container "C" is labelled "adhesions sigmoid colon" and consists of soft tissue measuring 3 x 1.5 x 0.4 cm. The tissue is trisected and submitted in toto as "C1".

Container "D" is labelled "adhesions left pelvis side wall" and consists of grey-white soft tissue measuring 3 x 0.9 x 0.3 cm. The tissue is bisected and submitted in toto as "D1".

Container "E" is labelled "uterus and cervix" and consists of a total hysterectomy specimen measuring 8.5 cm from corpus to cervix, 4.5 cm from comu-to-comu, 3 cm from anterior to posterior. The cervix is 2.5 cm in length. The os is slit in shape and measures 0.3 cm in maximum dimension. The uterus has a normal uterine contour with a smooth serosal surface. The bivalved specimen shows unremarkable cervix. The endometrium is 0.2 cm in thickness and the myometrium is 1.8 cm in thickness. Both the endometrium and myometrium are grossly unremarkable.

Representative sections are submitted as follows:

"E1-E2" -anterior/posterior ecto/endocervix

"E3-E4" -anterior endometrium/myometrium

"E5-E6" -posterior endometrium/myometrium

"E7" -cul-de-sac.

[page 3 of 3]
Container "F" is labelled "hepatic flexure biopsy" and consists of soft tissue measuring 1.5 x 1 x 0.2 cm. The tissue is submitted in toto as "F1".

Container "G" is labelled "omentum" and consists of omental fat measuring 23 x 5.5 x 1 cm. Sectioning of the omentum shows unremarkable fat.

No nodule or firm area identified.

Representative sections are submitted as "G1-G5".

Container "H" is labelled "adhesions cul-de-sac" and consists of dark brown soft tissue measuring 2 x 1.5 x 0.2 cm. The tissue is submitted in toto as "H1".

Intraoperative Consultation:

FSA/1

Gross Description: 10 cm 330 g torn capsule, ?rupture.

This area painted black.

Final Gross Description: Adhesions cul-de-sac, ?rupture. Secondary.

Source: NCI Genomic Data Commons file ae53517a-272b-440e-a250-772478328c36 (TCGA-36-1577.0C55B26C-CCF8-4223-9F5E-157BBDF6E5DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).